Somatic mutation profile of tumor specimen TCGA-FI-A2D6-01A (aliquot TCGA-FI-A2D6-01A-11D-A17D-09) from TCGA case TCGA-FI-A2D6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,060 days).
Specimen TCGA-FI-A2D6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d69c4a08-b2ac-4cf9-ab3d-c2ad08181660.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2D6-10A (Blood Derived Normal), aliquot TCGA-FI-A2D6-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b882d1ba-b482-413a-85d5-a621d8a858e1

The open-access MAF lists 800 somatic variants for this specimen: 602 protein-altering or splice-affecting, 175 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 360, Silent 175, Frame Shift Del 161, Frame Shift Ins 42, Nonsense Mutation 20, Splice Site 8, RNA 8, Intron 7, In Frame Del 6, 3'UTR 5, Splice Region 4, 3'Flank 2.

Variants (750 of 800; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC2 | c.5199dup p.K1734Qfs*419 | Frame Shift Ins (INS) | VAF 11/26 reads (42%) | catalogued as rs886040957; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- ATP8B1 | c.614del p.N205Mfs*33 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- CDK13 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796451, COSV99475171; ClinVar: pathogenic; called by muse, mutect2
- F8 | c.5961dup p.E1988Rfs*4 | Frame Shift Ins (INS) | VAF 19/61 reads (31%) | catalogued as rs387906460; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 28/54 reads (52%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1300del p.L434* | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs398123715, CD138467; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/63 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R2 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs886041602, COSV55847404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 60/65 reads (92%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WRN | c.15dup p.L6Ifs*12 | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | catalogued as rs878854133, COSV53298906; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV99258441; called by muse, mutect2, varscan2
- AADACL4 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs150325490; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 37/45 reads (82%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCB5 | c.2990A>T p.N997I (on ENST00000404938 / NM_001163941.2; = p.N552I on NM_178559.6) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99330181; called by muse, mutect2, varscan2
- ABCB7 | c.1627A>C p.S543R (on ENST00000373394 / NM_001271696.3; = p.S544R on NM_004299.6) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53722414; called by muse, mutect2, varscan2
- ABCC3 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99560089; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.3965G>T p.G1322V | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV99229950; called by muse, mutect2, varscan2
- ABHD8 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.134); catalogued as rs1392149270, COSV53112792; called by muse, mutect2, varscan2
- ACAT1 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99759475; called by muse, mutect2, varscan2
- ACSF2 | c.534dup p.K179Qfs*53 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | catalogued as rs1567855547; called by mutect2, pindel, varscan2
- ACTR2 | c.735+2T>C p.X245_splice | Splice Site (SNP) | VAF 27/43 reads (63%) | catalogued as COSV99574176; called by muse, mutect2, varscan2
- ACVR1B | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV99232280; called by muse, mutect2, varscan2
- ADAD1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV99636470; called by muse, mutect2, varscan2
- ADGRG4 | c.8862del p.F2955Lfs*9 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as COSV99794904; called by pindel, varscan2
- AGAP3 | c.347A>T p.Y116F (on ENST00000622464; = p.Y152F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100103979; called by muse, mutect2, varscan2
- AGTPBP1 | c.3673C>A p.L1225I (on ENST00000357081 / NM_001330701.2; = p.L1185I on NM_015239.2) | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); catalogued as COSV100430470; called by muse, mutect2, varscan2
- AKAP12 | c.4421C>A p.P1474H | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV99484742; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 30/38 reads (79%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALDH4A1 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs199624169; called by muse, mutect2, varscan2
- ALPP | c.976del p.R326Afs*25 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | catalogued as rs752094035; called by mutect2, varscan2
- ANK2 | c.9622G>A p.A3208T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100004867; called by muse, mutect2
- ANKAR | c.3254C>A p.P1085Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99854850; called by muse, mutect2, varscan2
- ANKLE1 | c.1082del p.P361Hfs*30 (on ENST00000394458; = p.P307Hfs*30 on NM_152363.6) | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | catalogued as rs778834689; called by mutect2, pindel, varscan2
- ANKRD12 | c.4577del p.N1526Mfs*10 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs768306357; called by mutect2, pindel, varscan2
- ANO2 | c.1982T>C p.M661T (on ENST00000356134 / NM_001278597.3; = p.M665T on NM_001278596.3) | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59040186; called by muse, mutect2, varscan2
- ANO4 | c.2618A>G p.Y873C (on ENST00000392977 / NM_001286615.2; = p.Y838C on NM_178826.4) | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100154164; called by muse, mutect2, varscan2
- APOOL | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100920992; called by muse, mutect2, varscan2
- APPL2 | c.55-1G>A p.X19_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99315260; called by muse, mutect2, varscan2
- AQP7 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1162875098, COSV99954065; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARMH3 | c.793_795del p.E265del | In Frame Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs1240965222; called by pindel, varscan2
- ASCC2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs772979948, COSV57072978; called by muse, mutect2, varscan2
- ASPHD1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1397977158, COSV100436007; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATE1 | c.909C>A p.H303Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99817946; called by muse, mutect2, varscan2
- ATG16L1 | c.1262C>T p.A421V (on ENST00000392017 / NM_030803.7; = p.A402V on NM_017974.4) | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.756); catalogued as rs751543614, COSV61465941; called by muse, mutect2, varscan2
- ATP1A4 | c.276del p.T93Pfs*48 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as rs760258351; called by mutect2, pindel, varscan2
- ATP6V1H | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100778903; called by muse, mutect2, varscan2
- ATP8B2 | c.1745G>A p.R582Q (on ENST00000672630; = p.R549Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs755275968, COSV100528133, COSV100528354; called by muse, mutect2, varscan2
- AXL | c.2039T>C p.L680P (on ENST00000301178 / NM_021913.5; = p.L671P on NM_001699.6) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99997474; called by muse, mutect2, varscan2
- B4GALT1 | c.773A>C p.N258T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101123025; called by muse, mutect2, varscan2
- BABAM2 | c.488dup p.N163Kfs*6 | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | catalogued as rs373964958; called by mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 24/40 reads (60%) | catalogued as rs751794665; called by mutect2, varscan2
- BEST4 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100944051; called by muse, mutect2, varscan2
- BMPR2 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.543); catalogued as rs751749720, COSV101001811; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 22/24 reads (92%) | catalogued as rs749043197; called by mutect2, varscan2
- BSN | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs773050937, COSV99609647; called by muse, mutect2, varscan2
- C14orf39 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100408242; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs781818365; called by mutect2, pindel, varscan2
- CAAP1 | c.571del p.I191Ffs*2 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs754356646, COSV61700397; called by mutect2, varscan2
- CACNA1F | c.4894C>T p.R1632W | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59904148, COSV59907143; called by muse, mutect2, varscan2
- CACNA1G | c.5056T>C p.S1686P | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100662823; called by muse, mutect2, varscan2
- CACNA1S | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62942496; called by muse, mutect2, varscan2
- CACNG5 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs759246922; called by muse, mutect2
- CALML3 | c.132dup p.T45Hfs*11 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | catalogued as rs1176578229; called by mutect2, pindel, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARD14 | c.844-2A>G p.X282_splice | Splice Site (SNP) | VAF 44/82 reads (54%) | catalogued as COSV100712649, COSV60127168; called by muse, mutect2, varscan2
- CASKIN2 | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1475195729, COSV100051125; called by muse, mutect2, varscan2
- CATSPERD | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV100486994; called by muse, mutect2, varscan2
- CATSPERG | c.1904T>G p.I635S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99287093; called by muse, mutect2, varscan2
- CCDC110 | c.761del p.K254Sfs*38 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs1561162074; called by mutect2, pindel, varscan2
- CCDC137 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1444365636, COSV100235872; called by muse, mutect2, varscan2
- CCDC146 | c.866del p.N289Mfs*2 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV104375271; called by mutect2, pindel, varscan2
- CCDC160 | c.940T>C p.S314P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV100892146; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 17/28 reads (61%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCNA2 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV99145204; called by muse, mutect2, varscan2
- CD1A | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99192689; called by muse, mutect2, varscan2
- CDH11 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.866); catalogued as rs866744133, COSV99220161; called by muse, mutect2, varscan2
- CDH4 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs760357766, COSV100849956; called by muse, mutect2
- CDK5RAP2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs367746734; called by muse, mutect2, varscan2
- CECR2 | c.2520dup p.N841Qfs*5 (on ENST00000342247 / NM_001290047.2; = p.N658Qfs*5 on NM_001290046.1) | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs754411618; called by mutect2, varscan2
- CELF5 | c.1096T>A p.Y366N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV99486292; called by muse, mutect2, varscan2
- CEP350 | c.7580C>T p.A2527V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV100855462; called by muse, mutect2, varscan2
- CFAP157 | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100077184; called by muse, mutect2, varscan2
- CFAP45 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141306445; called by muse, mutect2, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs763364101; called by mutect2, varscan2
- CFAP74 | c.4462del p.L1488Wfs*8 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as rs753357875; called by mutect2, pindel, varscan2
- CHML | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV100088003, COSV59365871; called by muse, mutect2, varscan2
- CHRM4 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100708905; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs752250702; called by mutect2, varscan2
- CKMT2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.511); catalogued as rs1216063009, COSV54173456; called by muse, mutect2, varscan2
- CLCN7 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as rs1428864451, COSV99247761; called by muse, mutect2, varscan2
- CLIC5 | c.718G>A p.V240M (on ENST00000185206 / NM_001370649.1; = p.V81M on NM_016929.5) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs142218776; called by muse, mutect2, varscan2
- CLMN | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100113101; called by muse, mutect2, varscan2
- CLPTM1 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV100494106; called by muse, mutect2, varscan2
- CLSTN2 | c.871G>C p.A291P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101515968; called by muse, mutect2, varscan2
- CNNM2 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1201563234, COSV100881956; called by muse, mutect2, varscan2
- COCH | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0); catalogued as COSV53549633; called by muse, mutect2, varscan2
- COL27A1 | c.3058C>A p.P1020T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100621423; called by muse, mutect2, varscan2
- COL7A1 | c.5189G>A p.R1730Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs774602003, COSV100098110; called by muse, mutect2, varscan2
- COL9A1 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295965; called by muse, mutect2, varscan2
- COP1 | c.696C>A p.N232K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100444125; called by muse, mutect2, varscan2
- COPG1 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59117423; called by muse, mutect2, varscan2
- CREB3 | c.435+2T>C p.X145_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100148406; called by muse, mutect2, varscan2
- CROCC | c.1841T>C p.V614A | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100978480; called by muse, mutect2, varscan2
- CRTC2 | c.818del p.G273Afs*29 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs771895874; called by mutect2, pindel, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs747248693; called by mutect2, varscan2
- CTDP1 | c.861T>G p.L287= | Splice Region (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99311337; called by muse, mutect2, varscan2
- DAAM1 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV100658648; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs751187768; called by mutect2, varscan2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DBX1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319012874, COSV99910372; called by muse, mutect2, varscan2
- DCN | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs993484273, COSV50007195; called by muse, mutect2, varscan2
- DENND6A | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100231690; called by muse, mutect2, varscan2
- DGKD | c.514G>A p.A172T (on ENST00000264057 / NM_152879.3; = p.A128T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs779077238, COSV51049921; called by muse, mutect2, varscan2
- DHDDS | c.517dup p.V173Gfs*10 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | catalogued as rs1272594778; called by mutect2, pindel, varscan2
- DHX34 | c.2279dup p.G761Rfs*4 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs763046010; called by mutect2, varscan2
- DHX34 | c.3064dup p.H1022Pfs*24 | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | catalogued as rs760422732; called by mutect2, pindel, varscan2
- DHX38 | c.1265T>C p.V422A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV99194702; called by muse, mutect2, varscan2
- DIDO1 | c.3938C>T p.P1313L | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56619460; called by muse, mutect2, varscan2
- DLG5 | c.4442dup p.A1482Sfs*51 | Frame Shift Ins (INS) | VAF 21/50 reads (42%) | catalogued as rs778796396; called by mutect2, varscan2
- DMD | c.7550T>C p.M2517T | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100630024; called by muse, mutect2, varscan2
- DMTF1 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100487565; called by muse, mutect2, varscan2
- DMWD | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1377999386, COSV99537539; called by muse, mutect2, varscan2
- DMXL2 | c.5663C>T p.T1888I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99199035; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF3 | c.1171C>A p.H391N (on ENST00000524407 / NM_001256715.2; = p.H438N on NM_178837.4) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV100788055; called by muse, mutect2, varscan2
- DNAH7 | c.4424G>A p.R1475Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs778327508, COSV56787593; called by muse, mutect2, varscan2
- DNAJC22 | c.224del p.P75Lfs*2 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs751047585; called by mutect2, pindel, varscan2
- DNMT1 | c.4462G>A p.A1488T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs749413587, COSV100533250; called by muse, mutect2, varscan2
- DOCK6 | c.5946G>T p.E1982D | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV53915250, COSV99627052; called by muse, mutect2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 43/81 reads (53%) | catalogued as rs748134881; called by mutect2, varscan2
- DPEP3 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs780496390, COSV99262969; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs369293935; called by mutect2, varscan2
- EFNA4 | c.535del p.D179Tfs*15 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs754580525; called by mutect2, pindel, varscan2
- EIF2AK4 | c.4892del p.K1631Rfs*48 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | catalogued as rs1400253542; called by mutect2, pindel, varscan2
- ELL2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs571687811, COSV52983899, COSV52986297; called by muse, mutect2
- EMC3 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs1015931293, COSV99793933; called by muse, mutect2, varscan2
- EMSY | c.3062C>T p.T1021I | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV100596156; called by muse, mutect2, varscan2
- EP400 | c.5044G>A p.A1682T | Missense Mutation (SNP) | VAF 84/135 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100202632; called by muse, mutect2, varscan2
- EPB41L4B | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as rs1460539007, COSV65797829, COSV65798328; called by muse, mutect2, varscan2
- EPG5 | c.1339A>G p.N447D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV99958402; called by muse, mutect2, varscan2
- EPHA2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs773163502, COSV64453099; called by muse, mutect2, varscan2
- ERMAP | c.1364T>C p.I455T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100072457; called by muse, mutect2, varscan2
- ESAM | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV53448927; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs775950025; called by mutect2, varscan2
- EXO1 | c.917A>C p.D306A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100800292; called by muse, mutect2, varscan2
- EXOSC5 | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99524858; called by muse, mutect2, varscan2
- F2R | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs770087836, COSV100058299; called by muse, mutect2, varscan2
- FAM168B | c.517dup p.H173Pfs*65 | Frame Shift Ins (INS) | VAF 13/24 reads (54%) | catalogued as rs905339801; called by mutect2, varscan2
- FAM24A | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV100925095; called by muse, mutect2, varscan2
- FANCB | c.1107T>C p.S369= | Splice Region (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100146727; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 21/45 reads (47%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FAT3 | c.12265G>T p.G4089W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99972717; called by muse, mutect2, varscan2
- FAT4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67895884; called by muse, mutect2, varscan2
- FBLN2 | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.585); catalogued as COSV99852955; called by muse, mutect2, varscan2
- FBXO31 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100291665; called by muse, mutect2, varscan2
- FBXW10 | c.565T>C p.S189P | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.36); catalogued as COSV100111857; called by muse, mutect2, varscan2
- FCGBP | c.2800G>A p.V934M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1457888064; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 31/65 reads (48%) | catalogued as rs144178676; called by mutect2, varscan2
- FLII | c.2803G>A p.V935I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.762); catalogued as rs199804606, COSV100375781; called by muse, mutect2, varscan2
- FLNA | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200084085, COSV100775430; called by muse, mutect2, varscan2
- FLNB | c.7123G>A p.V2375I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs767864936, COSV99915675; called by muse, mutect2, varscan2
- FLNC | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs781101985, COSV100369020; called by muse, mutect2
- FN1 | c.5119G>A p.D1707N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.779); catalogued as rs775247659, COSV100118585; called by muse, mutect2, varscan2
- FOLH1 | c.1900dup p.S634Ffs*15 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | catalogued as rs1446664569; called by mutect2, pindel, varscan2
- FOLR1 | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.372); catalogued as COSV100398618; called by muse, mutect2, varscan2
- FRMPD4 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1461743457, COSV66220818; called by muse, mutect2, varscan2
- FSTL4 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs374211071; called by muse, mutect2, varscan2
- FTCD | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148763241, COSV52427797; called by muse, mutect2, varscan2
- FZD8 | c.1615C>T p.L539F | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101020283; called by muse, mutect2, varscan2
- GABRB2 | c.1357C>T p.R453* (on ENST00000274547; = p.R415* on NM_000813.3) | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as rs1461566727, COSV99197652; called by muse, mutect2, varscan2
- GABRB2 | c.1020A>T p.K340N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV99197694; called by muse, mutect2, varscan2
- GAL3ST4 | c.713del p.P238Hfs*85 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs1332058293; called by mutect2, pindel, varscan2
- GALK1 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV99565108; called by muse, mutect2
- GALNS | c.1466G>A p.C489Y | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99243573; called by muse, mutect2
- GAS8 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99244313; called by muse, mutect2, varscan2
- GCNT3 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101251896; called by muse, mutect2, varscan2
- GET3 | c.630_631insT p.G211Wfs*30 | Frame Shift Ins (INS) | VAF 23/47 reads (49%) | catalogued as COSV100628310; called by mutect2, pindel, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 22/40 reads (55%) | catalogued as rs763147690; called by mutect2, varscan2
- GJB1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.749); catalogued as rs781315897, COSV100661312, COSV62139582; called by muse, mutect2, varscan2
- GJD4 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100397403; called by muse, mutect2, varscan2
- GNRHR | c.769A>G p.N257D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV99892424; called by muse, mutect2, varscan2
- GOLGA3 | c.1867C>T p.Q623* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99213305; called by muse, mutect2, varscan2
- GOLGB1 | c.4972_4974del p.K1658del | In Frame Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs1560230502; called by pindel, varscan2
- GPATCH2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150988724; called by muse, mutect2, varscan2
- GPR158 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV66269390; called by muse, mutect2, varscan2
- GPR179 | c.1741G>A p.A581T (on ENST00000621958; = p.A580T on NM_001004334.4) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239866129; called by muse, mutect2, varscan2
- GPR26 | c.849del p.Y284Tfs*26 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as COSV52933844; called by mutect2, pindel, varscan2
- GPR85 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99775188; called by muse, mutect2, varscan2
- GPSM1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.255); catalogued as COSV100696677, COSV100696706; called by muse, mutect2, varscan2
- GREB1 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs778284838, COSV52194132; called by muse, mutect2, varscan2
- GRIK3 | c.2707C>A p.P903T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100902256, COSV100902404, COSV100902522; called by muse, mutect2, varscan2
- GRIK3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs755366301, COSV66135882, COSV66139002; called by muse, mutect2, varscan2
- GRM4 | c.1906T>C p.C636R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100946988; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 44/110 reads (40%) | catalogued as rs754199513; called by mutect2, varscan2
- H1-1 | c.513del p.K171Nfs*5 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as COSV55119441; called by mutect2, pindel, varscan2
- HAUS3 | c.660dup p.Q221Tfs*8 | Frame Shift Ins (INS) | VAF 19/42 reads (45%) | catalogued as rs1321737329; called by mutect2, pindel, varscan2
- HEATR1 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63982361; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HGS | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs766958884, COSV100230869; called by muse, mutect2, varscan2
- HGS | c.1621_1623del p.K541del | In Frame Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs1173945236; called by mutect2, pindel, varscan2
- HIRA | c.2798A>G p.H933R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as COSV99601058; called by muse, mutect2, varscan2
- HIRA | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs761210709, COSV54276348; called by muse, mutect2, varscan2
- HLX | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.2); catalogued as rs371016648; called by muse, mutect2, varscan2
- HNRNPR | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 23/35 reads (66%) | catalogued as COSV56424609; called by muse, mutect2, varscan2
- HNRNPU | c.835C>T p.R279C (on ENST00000283179; = p.R341C on NM_004501.3) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1448881929, COSV51693191; called by muse, mutect2, varscan2
- HS3ST5 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.216); catalogued as rs762269276, COSV100451539, COSV57147362; called by muse, mutect2, varscan2
- HS3ST6 | c.613C>A p.R205S | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV99562930; called by muse, mutect2, varscan2
- HSD17B3 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100931253, COSV64558439; called by muse, mutect2, varscan2
- HSPG2 | c.11516C>T p.A3839V | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs148456372; called by muse, mutect2, varscan2
- IDH3A | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs762865075, COSV51904326; called by muse, mutect2, varscan2
- IGFLR1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs572529184, COSV53073663; called by muse, mutect2, varscan2
- IGHD6-13 | c.16T>C p.W6R | Missense Mutation (SNP) | VAF 96/197 reads (49%) | catalogued as rs781992550; called by muse, mutect2, varscan2
- IL17RE | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | catalogued as rs144881083; called by muse, mutect2, varscan2
- IL1RAP | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs750161003, COSV99300178; called by muse, mutect2, varscan2
- INO80D | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs893370188, COSV101305904; called by muse, mutect2, varscan2
- INSRR | c.2948G>T p.R983L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100948273; called by muse, mutect2, varscan2
- ISOC2 | c.598C>A p.Q200K (on ENST00000425675 / NM_001136201.2; = p.Q216K on NM_024710.3) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV99321387; called by muse, mutect2, varscan2
- ITIH4 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.014); catalogued as rs779370674, COSV99820084; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 37/84 reads (44%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JMJD1C | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101232543; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs752059864; called by mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCNH2 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51125763, COSV51218114; called by muse, mutect2, varscan2
- KCNH7 | c.1885G>T p.G629* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as COSV100037286; called by muse, mutect2, varscan2
- KCNJ15 | c.37del p.L13Wfs*2 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as COSV100154199; called by mutect2, pindel, varscan2
- KCNJ5 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as rs185412918; called by muse, mutect2, varscan2
- KDM8 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149728125, COSV53729326; called by muse, mutect2, varscan2
- KHDC4 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs1213718424, COSV64165947; called by muse, mutect2, varscan2
- KIAA1217 | c.1487del p.P496Lfs*26 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as COSV56813511; called by mutect2, pindel, varscan2
- KIAA1522 | c.172del p.H58Tfs*24 (on ENST00000373480 / NM_001198972.2; = p.H117Tfs*24 on NM_020888.3) | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs767600627; called by mutect2, pindel, varscan2
- KIDINS220 | c.2891G>T p.R964M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99876646; called by muse, mutect2, varscan2
- KIF13B | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs754537721, COSV101568725; called by muse, mutect2, varscan2
- KIFAP3 | c.697del p.R233Dfs*25 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as COSV63030906; called by mutect2, pindel, varscan2
- KLHL10 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.098); catalogued as rs1204134487, COSV99509579; called by muse, mutect2, varscan2
- KLHL6 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs774841844, COSV100385149; called by muse, mutect2, varscan2
- KMT2B | c.3676C>T p.H1226Y | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55859506; called by muse, mutect2, varscan2
- KNL1 | c.4175A>G p.E1392G (on ENST00000346991 / NM_170589.5; = p.E1366G on NM_144508.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV100707216; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs764099275; called by mutect2, varscan2
- KRT28 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768445733, COSV60686608; called by muse, mutect2, varscan2
- KRT6B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs374881736, COSV99361137; called by muse, mutect2, varscan2
- KRTAP1-5 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs544705280, COSV62624235; called by muse, mutect2, varscan2
- LAMA3 | c.4973del p.P1658Lfs*91 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as rs759440110; called by mutect2, pindel, varscan2
- LAMB4 | c.4718T>C p.L1573S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.021); catalogued as rs1208504686, COSV99226176; called by muse, mutect2, varscan2
- LENG9 | c.1352G>A p.C451Y | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100003041; called by muse, mutect2, varscan2
- LIG3 | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs757797167, COSV52005856; called by muse, mutect2, varscan2
- LIN54 | c.809-2A>C p.X270_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100465103; called by muse, mutect2
- LPCAT2 | c.622T>C p.S208P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV100045366, COSV100045506; called by muse, mutect2, varscan2
- LRP2 | c.1627A>G p.M543V | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1175222629, COSV99790875; called by muse, mutect2, varscan2
- LRRC49 | c.185G>C p.S62T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.049); catalogued as COSV99538445; called by muse, mutect2, varscan2
- LSR | c.1858C>T p.P620S (on ENST00000361790; = p.P601S on NM_015925.6) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs751322120, COSV99723556; called by muse, mutect2, varscan2
- LZTS3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.94); catalogued as rs759999966, COSV61277364; called by muse, mutect2, varscan2
- MACROH2A2 | c.438dup p.K147Efs*21 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as rs775088830; called by mutect2, varscan2
- MAGEH1 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.37); catalogued as COSV100746852; called by muse, mutect2, varscan2
- MAN1B1 | c.1014del p.L339Sfs*2 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs752359237; called by mutect2, pindel, varscan2
- MAP2K2 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs772831628, COSV53569585; ClinVar: uncertain significance; called by muse, varscan2
- MARCHF6 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs775679238, COSV99930294; called by muse, mutect2, varscan2
- MCM3AP | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 22/36 reads (61%) | catalogued as COSV99387662; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- METTL26 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100037601; called by muse, mutect2, varscan2
- MFAP3L | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs746378548, COSV100852721; called by muse, mutect2, varscan2
- MGAM | c.5446G>A p.V1816M | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs770357204, COSV101527811; called by muse, mutect2, varscan2
- MGAT5 | c.457T>C p.Y153H | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV99925301; called by muse, mutect2, varscan2
- MINDY2 | c.1847del p.N616Ifs*41 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs1282883369; called by mutect2, pindel, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs750307488; called by mutect2, varscan2
- MN1 | c.1271A>G p.E424G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.385); catalogued as COSV100180282; called by muse, mutect2, varscan2
- MOCS2 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100799084; called by muse, mutect2, varscan2
- MS4A13 | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100981233; called by muse, mutect2, varscan2
- MSANTD2 | c.34A>G p.N12D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99516074; called by muse, mutect2, varscan2
- MT1E | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100042406; called by muse, mutect2
- MTERF2 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99527021; called by muse, mutect2, varscan2
- MTM1 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100080800; called by muse, mutect2, varscan2
- MTSS1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377023038; called by muse, mutect2, varscan2
- MUC6 | c.3592C>T p.P1198S | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as COSV70151709; called by muse, mutect2, varscan2
- MYBPC3 | c.3781G>A p.E1261K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs730880141, COSV99921185; ClinVar: uncertain significance; called by mutect2, varscan2
- NAA50 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99568915; called by muse, mutect2, varscan2
- NCKAP5 | c.5293A>G p.R1765G | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV100494932; called by muse, mutect2, varscan2
- NCOR2 | c.6571G>A p.A2191T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV100658098; called by muse, mutect2, varscan2
- NFKBIB | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs371119134, COSV58002690; called by muse, mutect2, varscan2
- NINL | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746614158, COSV54005357; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs145147241; called by mutect2, varscan2
- NISCH | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV100617745; called by muse, mutect2, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs767007251; called by mutect2, varscan2
- NOBOX | c.961del p.A321Pfs*27 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | catalogued as rs1174738024; called by mutect2, pindel, varscan2
- NOTCH3 | c.6102del p.G2035Vfs*50 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs771517374; called by mutect2, pindel, varscan2
- NOVA1 | c.101dup p.E35* | Frame Shift Ins (INS) | VAF 27/59 reads (46%) | catalogued as rs765756993; called by mutect2, varscan2
- NPAP1 | c.317del p.P106Rfs*9 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs762821502; called by mutect2, pindel, varscan2
- NRCAM | c.1522G>T p.G508* (on ENST00000379028 / NM_001371124.1; = p.G502* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV61051455; called by muse, mutect2, varscan2
- NTMT1 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52964693; called by muse, mutect2, varscan2
- NUAK2 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100904144; called by muse, mutect2, varscan2
- NUP214 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as rs755153760, COSV100845425; called by muse, mutect2, varscan2
- NUTM1 | c.2605A>G p.M869V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs774126770, COSV100149280; called by muse, mutect2, varscan2
- OBSCN | c.9880C>T p.R3294W | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as rs746656920, COSV52854860; called by muse, mutect2, varscan2
- OBSCN | c.12560C>T p.A4187V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV99486451; called by muse, mutect2, varscan2
- OBSCN | c.18512C>T p.A6171V | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as rs974057776, COSV99486454; called by muse, mutect2, varscan2
- ODF2 | c.1787T>A p.L596Q (on ENST00000434106 / NM_153433.2; = p.L572Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100655044; called by muse, mutect2, varscan2
- OPALIN | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.286); catalogued as COSV100959718; called by muse, mutect2, varscan2
- OR10G7 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100390130; called by muse, mutect2, varscan2
- OR10H5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs145697877; called by muse, mutect2
- OR2T35 | c.849del p.M284Cfs*9 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs776284896; called by mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR5AU1 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1175477965, COSV58615504; called by muse, mutect2, varscan2
- OR8B12 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100172983; called by muse, mutect2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs750679212; called by mutect2, varscan2
- OTX2 | c.116G>A p.R39H (on ENST00000408990 / NM_172337.3; = p.R47H on NM_021728.4) | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100257927; called by muse, mutect2, varscan2
- PACS1 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1041485549, COSV57697010; called by muse, mutect2, varscan2
- PANK4 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs748809177, COSV101022597; called by muse, mutect2, varscan2
- PANX1 | c.322-2A>G p.X108_splice | Splice Site (SNP) | VAF 15/24 reads (63%) | catalogued as COSV99922121; called by muse, mutect2, varscan2
- PASK | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs781751338, COSV52151261, COSV99300480; called by muse, mutect2, varscan2
- PCDH15 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV100229911, COSV57285609; called by muse, mutect2, varscan2
- PCDH17 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as rs770729682, COSV64975717; called by muse, mutect2, varscan2
- PCDHA3 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs782553261, COSV100793868; called by muse, mutect2, varscan2
- PCDHB6 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs782478636, COSV50693143; called by muse, varscan2
- PCDHGA12 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52745331; called by muse, mutect2, varscan2
- PCNT | c.4555G>A p.D1519N | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs762126145, COSV100856216; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFA | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100627406; called by muse, mutect2, varscan2
- PEAR1 | c.981C>G p.C327W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99442659; called by muse, mutect2, varscan2
- PFAS | c.2420G>A p.S807N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1430202266, COSV100119240; called by muse, mutect2, varscan2
- PFKM | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 134/217 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs768496070, COSV56659110; called by muse, mutect2, varscan2
- PGAM2 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99803984; called by muse, mutect2
- PHF2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs773872264, COSV100823383; called by muse, mutect2, varscan2
- PHF2 | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1419148418, COSV100823384; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PIGZ | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1330558229, COSV99434030; called by muse, mutect2, varscan2
- PIK3CD | c.2007G>T p.E669D | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100740643; called by muse, mutect2, varscan2
- PIK3R1 | c.2050C>T p.P684S (on ENST00000521381 / NM_181523.3; = p.P414S on NM_181504.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57144780; called by muse, mutect2, varscan2
- PKD1 | c.3701C>T p.A1234V | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs545640319, COSV51913510; called by muse, mutect2, varscan2
- PKD1 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); catalogued as rs752035888, COSV99239371; called by muse, mutect2, varscan2
- PLA2G4F | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767391879, COSV51828321; called by muse, mutect2, varscan2
- PLCB3 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.153); catalogued as rs960193376, COSV99657867; called by muse, mutect2, varscan2
- PLD2 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as rs772123505, COSV99562821; called by muse, mutect2, varscan2
- PLS1 | c.1090A>T p.N364Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538423; called by muse, mutect2
- PNKD | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780464180, COSV51240269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNMA5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs782553555, COSV62625985; called by muse, mutect2, varscan2
- PNMA8B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.496); catalogued as rs764238832, COSV100885553; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 42/107 reads (39%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- POGLUT3 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); catalogued as COSV100052879; called by muse, mutect2, varscan2
- POLR1B | c.446del p.R149Lfs*23 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as COSV99638598; called by mutect2, pindel, varscan2
- POLR3H | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as rs200820170, COSV99347868; called by muse, mutect2, varscan2
- POM121C | c.3366del p.F1123Sfs*5 (on ENST00000607367; = p.F881Sfs*5 on NM_001099415.3) | Frame Shift Del (DEL) | VAF 38/91 reads (42%) | catalogued as COSV57548940; called by mutect2, pindel, varscan2
- PPP2R3B | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs374748842, COSV66813409; called by muse, mutect2, varscan2
- PPP2R5D | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99775939; called by muse, mutect2, varscan2
- PPP6R1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as rs762448448, COSV101336978; called by muse, mutect2, varscan2
- PRAMEF4 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV99340385; called by muse, mutect2, varscan2
- PRDM15 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746274698, COSV99521190; called by muse, mutect2, varscan2
- PRKDC | c.8257C>T p.R2753* | Nonsense Mutation (SNP) | VAF 29/47 reads (62%) | catalogued as COSV58049590; called by muse, mutect2, varscan2
- PRMT7 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs773644503, COSV100267350; called by muse, mutect2, varscan2
- PRMT7 | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV100267352; called by muse, mutect2, varscan2
- PROM2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs149240402; called by muse, mutect2, varscan2
- PROSER3 | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99994848; called by muse, mutect2, varscan2
- PRRC2B | c.4312G>A p.G1438R | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs772703895, COSV100622419; called by muse, mutect2, varscan2
- PRSS38 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs373544174, COSV64540733; called by muse, mutect2, varscan2
- PRSS8 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779417018, COSV99571589; called by muse, mutect2, varscan2
- PSMC4 | c.598dup p.R200Pfs*43 | Frame Shift Ins (INS) | VAF 13/37 reads (35%) | catalogued as rs765768285; called by mutect2, varscan2
- PTBP1 | c.1472G>A p.R491H (on ENST00000349038 / NM_031991.4; = p.R517H on NM_002819.5) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1466338768, COSV100609260; called by muse, mutect2, varscan2
- PYDC1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs1473530864, COSV57251731; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs755727862; called by mutect2, varscan2
- R3HDM1 | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.419); catalogued as COSV99927057; called by muse, mutect2, varscan2
- RAB25 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs767067172, COSV100737442; called by muse, mutect2, varscan2
- RASGRP4 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99498908; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 20/34 reads (59%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.293dup p.D99Rfs*6 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | catalogued as rs764709206; called by mutect2, varscan2
- RBPJ | c.252del p.E85Nfs*21 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs761285857; called by mutect2, varscan2
- RFLNB | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs528686861, COSV100225148; called by muse, mutect2, varscan2
- RFLNB | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs782276808, COSV61239609; called by muse, mutect2, varscan2
- RGS16 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.594); catalogued as rs569649727, COSV62375928; called by muse, mutect2, varscan2
- RGS9 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs374456012; called by muse, mutect2, varscan2
- RHOT2 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1229285413, COSV54808260; called by muse, mutect2, varscan2
- ROCK1 | c.3881A>T p.D1294V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101296663; called by muse, varscan2
- RP1 | c.3244C>A p.L1082I | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV99609334; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA1 | c.1104del p.S369Afs*18 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs745561139; called by mutect2, pindel, varscan2
- RPS6KA5 | c.1937T>A p.F646Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV100003444; called by muse, mutect2, varscan2
- RSC1A1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs776397465, COSV100197439; called by muse, mutect2, varscan2
- RSPH10B | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100383026; called by mutect2, varscan2
- RSRC2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.14); catalogued as COSV100063977; called by muse, mutect2, varscan2
- RUSC2 | c.2580G>T p.W860C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV100770972; called by muse, mutect2, varscan2
- SASH1 | c.2557G>A p.V853M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.475); catalogued as rs538165456, COSV100821558; called by muse, mutect2, varscan2
- SCN10A | c.3971C>T p.S1324L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs756046052, COSV71862048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN10A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs748821446, COSV101479595, COSV71860992; called by muse, mutect2, varscan2
- SDK1 | c.5656T>C p.Y1886H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101270057; called by muse, mutect2, varscan2
- SDK2 | c.1507dup p.Q503Pfs*115 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs753108327; called by mutect2, varscan2
- SEC16A | c.1790del p.P597Rfs*18 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as rs1564534433; called by mutect2, pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SERINC4 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs143808872; called by muse, mutect2, varscan2
- SH3PXD2B | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs765472301, COSV100288672; called by muse, mutect2, varscan2
- SIRT6 | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100511476; called by muse, mutect2, varscan2
- SLC12A2 | c.1189-2A>G p.X397_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99321753; called by muse, mutect2
- SLC25A5 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100510530; called by muse, mutect2, varscan2
- SLC39A14 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.634); catalogued as rs536308326, COSV99250096; called by muse, mutect2
- SLC5A4 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs749298344, COSV99832260; called by muse, mutect2, varscan2
- SLC6A6 | c.1042C>A p.L348M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100692587; called by muse, mutect2, varscan2
- SLC6A8 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV99466459; called by muse, mutect2, varscan2
- SLC7A7 | c.1327T>C p.S443P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV99591396; called by muse, mutect2, varscan2
- SLC8B1 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV99176880; called by muse, mutect2, varscan2
- SLCO1B3 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs904458330, COSV99682471; called by muse, mutect2, varscan2
- SLITRK5 | c.2641C>A p.P881T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV100281387; called by muse, mutect2, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs774532876; called by mutect2, pindel, varscan2
- SMAD7 | c.626dup p.P210Sfs*25 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs747624971; called by mutect2, varscan2
- SMARCA4 | c.3484G>A p.G1162S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100759311, COSV60788440, COSV60801054; called by muse, mutect2, varscan2
- SMCR8 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100329375; called by muse, mutect2, varscan2
- SMNDC1 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100852200; called by muse, mutect2, varscan2
- SMNDC1 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100852205; called by muse, mutect2, varscan2
- SMURF1 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100742738; called by muse, mutect2, varscan2
- SOAT1 | c.1234T>C p.S412P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100859125; called by muse, mutect2, varscan2
- SON | c.5029A>G p.K1677E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs141495709; called by muse, mutect2, varscan2
- SORCS3 | c.1105C>A p.L369I | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV100865756; called by muse, mutect2, varscan2
- SOX9 | c.66del p.S23Afs*38 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as COSV55428538; called by mutect2, pindel, varscan2
- SPAG17 | c.3054G>A p.P1018= | Splice Region (SNP) | VAF 39/80 reads (49%) | catalogued as rs1369174978, COSV100311086; called by muse, mutect2, varscan2
- SPART | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as rs7321457; called by muse, mutect2, varscan2
- SPATA5 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs374627057, COSV99916721; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEN | c.2834T>G p.L945R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV101005766; called by muse, mutect2, varscan2
- SPPL2C | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100234229; called by muse, mutect2, varscan2
- SPTBN1 | c.6803A>G p.Y2268C | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100443696; called by muse, mutect2
- SPZ1 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57063263, COSV99698308; called by mutect2, varscan2
- SSH3 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV57383847; called by muse, varscan2
- SSR2 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs1558075860, COSV99828745; called by muse, mutect2, varscan2
- SSX2IP | c.17C>G p.T6S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.918); catalogued as COSV100642813; called by muse, mutect2, varscan2
- ST3GAL3 | c.1003G>A p.A335T (on ENST00000361392 / NM_174964.4; = p.A320T on NM_006279.5) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as CM131242, COSV99496189; called by muse, mutect2, varscan2
- ST8SIA2 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | PolyPhen probably damaging (0.994); catalogued as rs1313499627, COSV99184579; called by muse, mutect2, varscan2
- STAB1 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs373323793; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs752994755; called by mutect2, varscan2
- STAT2 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.011); catalogued as rs768593805, COSV99950770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK11IP | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as rs781224134, COSV99823646; called by muse, mutect2, varscan2
- STRBP | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV100724398; called by muse, mutect2, varscan2
- STX7 | c.613A>G p.S205G | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100908535, COSV63398954; called by muse, mutect2, varscan2
- SUN2 | c.1814A>G p.Q605R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99325948; called by muse, mutect2, varscan2
- SUPT6H | c.916A>G p.K306E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV100112926; called by muse, mutect2
- SUPT6H | c.4476G>T p.E1492D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV99973225; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SWI5 | c.280_281del p.L94Afs*3 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs1564375006; called by pindel, varscan2
- SYCP1 | c.1884del p.G629Vfs*8 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | catalogued as rs762984894, COSV65697419; called by mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYDE1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV99655217; called by muse, mutect2, varscan2
- SYNE1 | c.11439del p.G3814Vfs*4 (on ENST00000367255 / NM_182961.4; = p.G3799Vfs*4 on NM_033071.3) | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs34206565; called by mutect2, pindel, varscan2
- TADA3 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99809682; called by muse, mutect2, varscan2
- TAF3 | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | catalogued as COSV100720531; called by muse, mutect2, varscan2
- TAOK2 | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1223048815, COSV99663435; called by muse, mutect2, varscan2
- TAS1R3 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV100229964; called by muse, varscan2
- TATDN2 | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99813826; called by muse, mutect2, varscan2
- TBC1D22B | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs755058140, COSV65142853; called by muse, mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs751224053; called by mutect2, pindel, varscan2
- TF | c.2051G>A p.C684Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53921178, COSV99396579; called by muse, mutect2, varscan2
- THBS3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1340791242, COSV64250783; called by muse, mutect2, varscan2
- THEMIS | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100965687; called by muse, mutect2, varscan2
- TINF2 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs551919709, COSV57467995; called by muse, mutect2, varscan2
- TLCD3B | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs370399407; called by muse, mutect2, varscan2
- TLN2 | c.4808T>A p.V1603D | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs1310791489, COSV100170409; called by muse, mutect2, varscan2
- TLN2 | c.5597C>T p.A1866V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.28); catalogued as rs377502147; called by muse, mutect2, varscan2
- TLR4 | c.528T>G p.N176K (on ENST00000355622 / NM_138554.5; = p.N136K on NM_003266.4) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV100790703; called by muse, mutect2, varscan2
- TLR9 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs200200453, COSV100645784, COSV62345404; called by muse, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs754390908; called by mutect2, varscan2
- TMPRSS11B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV100219568; called by muse, varscan2
- TMPRSS11E | c.999G>T p.Q333H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV100542577; called by muse, mutect2
- TMPRSS12 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); catalogued as COSV101269175; called by muse, mutect2, varscan2
- TNNT3 | c.332G>A p.R111H (on ENST00000397301 / NM_001367846.1; = p.R100H on NM_006757.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208387518, COSV53488553; called by muse, mutect2, varscan2
- TNXB | c.10556C>T p.A3519V (on ENST00000647633; = p.A3272V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.34); catalogued as COSV100926803; called by muse, mutect2, varscan2
- TNXB | c.7211G>A p.R2404H (on ENST00000647633; = p.R2157H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs768307848, COSV100926804; called by muse, mutect2, varscan2
- TP73 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as rs1275012082, COSV60698746; called by muse, mutect2, varscan2
- TPPP2 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100069526; called by muse, mutect2, varscan2
- TPRA1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs376730796; called by muse, mutect2, varscan2
- TRABD2A | c.1366C>A p.L456M (on ENST00000409520 / NM_001277053.2; = p.L407M on NM_001080824.3) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.221); catalogued as COSV99409315; called by muse, mutect2, varscan2
- TRAM1L1 | c.394del p.S132Lfs*9 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs757906221; called by mutect2, pindel, varscan2
- TRIM11 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.222); catalogued as COSV52856651, COSV52859096; called by mutect2, varscan2
- TRIM3 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.149); catalogued as rs1224652817, COSV100624588; called by muse, mutect2, varscan2
- TRMT2B | c.637C>G p.P213A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100105763; called by muse, mutect2, varscan2
- TRPA1 | c.2017dup p.T673Nfs*9 | Frame Shift Ins (INS) | VAF 14/24 reads (58%) | catalogued as rs748693374; called by mutect2, varscan2
- TRPM1 | c.3281G>A p.R1094Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56632531; called by muse, mutect2, varscan2
- TSHZ3 | c.3187A>T p.T1063S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV99553258; called by muse, mutect2, varscan2
- TSKS | c.1046A>G p.Q349R | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV99883870; called by muse, mutect2, varscan2
- TTC26 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV58272148; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | catalogued as rs756650873; called by mutect2, varscan2
- TULP1 | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM156228, COSV100004460; called by muse, mutect2, varscan2
- UNC45A | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs777672118, COSV67817068; called by muse, mutect2, varscan2
- UTP25 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71966202; called by muse, mutect2, varscan2
- UTP4 | c.1622T>C p.L541P | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100077221; called by muse, mutect2, varscan2
- VCP | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202389474, COSV62721638; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs756863093; called by mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13C | c.9533C>A p.P3178H (on ENST00000644861 / NM_020821.3; = p.P3135H on NM_017684.5) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99830746; called by muse, mutect2, varscan2
- VPS13D | c.8275C>T p.R2759C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768679106, COSV50719659, COSV99169632; called by muse, mutect2, varscan2
- VPS41 | c.1163dup p.N388Kfs*3 | Frame Shift Ins (INS) | VAF 14/29 reads (48%) | catalogued as rs757692785; called by mutect2, varscan2
- VRK3 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100371931; called by muse, mutect2, varscan2
- WDR81 | c.5368C>T p.R1790C (on ENST00000409644 / NM_001163809.2; = p.R739C on NM_152348.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777571265, COSV100489374; called by muse, mutect2, varscan2
- XCR1 | c.40del p.Y14Tfs*33 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs1158688440; called by mutect2, pindel, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs745648385; called by mutect2, pindel, varscan2
- Z83844.2 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as rs752569280, COSV99312987; called by muse, mutect2, varscan2
- ZAP70 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.999); catalogued as COSV53852690; called by muse, mutect2, varscan2
- ZC2HC1C | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1054231428, COSV99473015; called by muse, mutect2, varscan2
- ZFHX3 | c.3628C>T p.R1210* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV51709176; called by muse, mutect2, varscan2
- ZNF202 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as rs1009410928, COSV60249218; called by muse, mutect2, varscan2
- ZNF304 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV56583475, COSV56586037, COSV99988940; called by muse, mutect2, varscan2
- ZNF483 | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV100493175; called by muse, mutect2, varscan2
- ZNF532 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100267379; called by muse, mutect2, varscan2
- ZNF560 | c.1160T>C p.V387A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.115); catalogued as COSV100039195; called by muse, mutect2, varscan2
- ZNF57 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as rs148390269, COSV60983064; called by muse, mutect2, varscan2
- ZNF609 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100441112; called by muse, mutect2, varscan2
- ZNF652 | c.772T>C p.W258R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100755733; called by muse, mutect2, varscan2
- ZNF665 | c.209G>A p.R70K (on ENST00000600412; = p.R135K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101128995; called by muse, mutect2, varscan2
- ZNF768 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as rs779909020, COSV99411703; called by muse, mutect2, varscan2
- ZNF770 | c.1077del p.V360Yfs*7 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | catalogued as COSV62544218; called by mutect2, varscan2
- ZSWIM4 | c.1517A>G p.E506G | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV99585585; called by muse, mutect2, varscan2
- A4GALT | c.201del p.T68Pfs*46 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- ACAN | c.2541del p.V848Cfs*97 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- ADAMDEC1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by mutect2, varscan2
- ANKRD20A2P | c.68del p.T23Rfs*82 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | called by mutect2, pindel, varscan2
- ARHGEF3 | c.279del p.S94Rfs*44 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- BAG6 | c.2780del p.G927Dfs*21 (on ENST00000676571; = p.G880Dfs*21 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- C17orf75 | c.464del p.L155* | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | called by mutect2, pindel, varscan2
- CACNA1E | c.3979_3981del p.K1327del | In Frame Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- CCDC43 | c.645_646del p.R216Dfs*60 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- CCN4 | c.488del p.P163Rfs*11 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- CCND1 | c.871_879del p.R291_V293del | In Frame Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel
- CELF2 | c.814dup p.M272Nfs*82 (on ENST00000416382 / NM_001025077.3; = p.M279Nfs*82 on NM_006561.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- CTCF | c.1348dup p.S450Kfs*2 | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- CYP3A7-CYP3A51P | c.1573del p.W525Gfs*? | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- DHX36 | c.578del p.N193Mfs*25 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- DNAH2 | c.12975del p.K4326Rfs*84 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- E2F3 | c.529dup p.T177Nfs*4 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- ERVW-1 | c.935dup p.P313Afs*61 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- FAM53C | c.629del p.P210Lfs*96 | Frame Shift Del (DEL) | VAF 38/109 reads (35%) | called by mutect2, pindel, varscan2
- FBXO34 | c.1454del p.L485Cfs*13 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- FKBP4 | c.372del p.N125Mfs*18 | Frame Shift Del (DEL) | VAF 54/98 reads (55%) | called by mutect2, varscan2
- FRAS1 | c.4032del p.M1345Cfs*38 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- GDF5 | c.157del p.L53Wfs*34 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- GTF3C4 | c.1720del p.W574Gfs*8 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- HDAC5 | c.760del p.L254Sfs*10 | Frame Shift Del (DEL) | VAF 13/19 reads (68%) | called by mutect2, varscan2
- HOXB3 | c.1094del p.P365Lfs*64 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- IGHV3-23 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- IRAG1 | c.465_467del p.E155del | In Frame Del (DEL) | VAF 21/51 reads (41%) | called by pindel, varscan2
- IRS2 | c.3947del p.P1316Lfs*15 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | called by mutect2, varscan2
- KANSL1 | c.536del p.G179Efs*23 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- KIF16B | c.1070del p.N357Tfs*24 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- KLB | c.770del p.P257Lfs*7 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- KRT12 | c.212dup p.G72Wfs*22 | Frame Shift Ins (INS) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- LPA | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LPIN3 | c.214dup p.E72Gfs*25 | Frame Shift Ins (INS) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- LZTS1 | c.312del p.K105Sfs*9 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- MAP1A | c.7434del p.R2479Gfs*4 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- MAP3K2 | c.120del p.K40Nfs*29 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | called by mutect2, pindel, varscan2
- MBD6 | c.809del p.P270Lfs*107 | Frame Shift Del (DEL) | VAF 34/68 reads (50%) | called by mutect2, pindel, varscan2
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | called by mutect2, varscan2
- MGAT5B | c.1509del p.E504Rfs*6 (on ENST00000569840 / NM_001199172.2; = p.E502Rfs*6 on NM_144677.3) | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- MKKS | c.1084dup p.H362Pfs*5 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- MRGPRX4 | c.560del p.L187Yfs*25 | Frame Shift Del (DEL) | VAF 45/141 reads (32%) | called by mutect2, pindel, varscan2
- MUSK | c.140dup p.M48Hfs*11 | Frame Shift Ins (INS) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- MVB12A | c.810dup p.S271Qfs*91 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- MYH10 | c.2162del p.F721Sfs*11 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- MYH3 | c.536_538dup p.G179dup | In Frame Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- MYO10 | c.3024del p.N1009Tfs*28 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- MYT1 | c.2332del p.E778Kfs*4 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- NBPF26 | c.2642T>G p.L881R (on ENST00000620612; = p.L619R on NM_001351372.1) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NEB | c.4696del p.S1566Vfs*38 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.7455del p.S2486Rfs*103 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- NYNRIN | c.3617del p.G1206Vfs*50 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- PADI1 | c.667_668del p.S223Gfs*14 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by pindel, varscan2
- PHF14 | c.946dup p.M316Nfs*14 | Frame Shift Ins (INS) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1344dup p.L449Ifs*3 (on ENST00000521381 / NM_181523.3; = p.L179Ifs*3 on NM_181504.4) | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.883del p.M295* | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | called by mutect2, pindel, varscan2
- PLEKHO1 | c.766del p.Q256Rfs*6 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- PUM1 | c.3545del p.P1182Lfs*35 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- RDX | c.191del p.K64Rfs*2 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- RNF146 | c.619_620del p.Q207Efs*31 (on ENST00000368314 / NM_001242850.2; = p.Q206Efs*31 on NM_030963.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by pindel, varscan2
- ROBO1 | c.2506del p.S836Pfs*27 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel
- SGPP1 | c.1068dup p.I357Hfs*44 | Frame Shift Ins (INS) | VAF 24/56 reads (43%) | called by mutect2, pindel, varscan2
- SLC12A1 | c.2724del p.G909Afs*14 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- SLC26A3 | c.983del p.P328Lfs*13 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- STRAP | c.356del p.G119Dfs*11 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- TBC1D10B | c.961_962del p.S321Lfs*20 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | called by pindel, varscan2
- TDRD9 | c.3933_3934dup p.V1312Efs*14 | Frame Shift Ins (INS) | VAF 31/68 reads (46%) | called by mutect2, varscan2
- THSD7A | c.4597dup p.T1533Nfs*5 | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- TOX3 | c.939dup p.E314Rfs*16 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- TRPM5 | c.2692del p.H898Mfs*34 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | called by mutect2, pindel, varscan2
- TXLNA | c.1548dup p.R517Qfs*57 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- UBN1 | c.558del p.K186Nfs*8 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- USP50 | c.829del p.R277Gfs*12 (on ENST00000616326; = p.R268Gfs*12 on NM_203494.5) | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- VGLL3 | c.473del p.P158Hfs*54 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- VPS13A | c.8653del p.Y2885Mfs*20 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | called by mutect2, varscan2
- VSNL1 | c.59_60del p.T20Rfs*3 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by pindel, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | called by mutect2, pindel, varscan2
- WSCD2 | c.1395_1396dup p.L466Hfs*19 | Frame Shift Ins (INS) | VAF 44/72 reads (61%) | called by mutect2, varscan2
- XIAP | c.470del p.N157Tfs*11 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- YLPM1 | c.761del p.P254Lfs*35 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- ZNF462 | c.6211del p.T2071Hfs*23 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- ZNF646 | c.671del p.G224Afs*58 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- ZNF773 | c.1104dup p.S369* | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- ABHD8 | c.513C>T p.G171= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV99395575; called by muse, mutect2, varscan2
- ACOT7 | c.936C>T p.A312= (on ENST00000377855 / NM_181864.3; = p.A302= on NM_007274.4) | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs376626576; called by muse, mutect2, varscan2
- ACTL7B | c.933C>T p.T311= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs776172037, COSV101012607; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4227T>C p.D1409= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV101000554; called by muse, mutect2, varscan2
- ADRA1D | c.1281C>G p.R427= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV101063202; called by muse, mutect2, varscan2
- AGBL2 | c.1200C>T p.Y400= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100102269; called by muse, mutect2, varscan2
- AHNAK | c.16029C>T p.D5343= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs142335428; called by muse, mutect2, varscan2
- AMOTL2 | c.90G>A p.T30= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs1290542031, COSV51438904; called by muse, mutect2, varscan2
- ANKS1A | c.2883G>A p.T961= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs143676161; called by muse, varscan2
- APOOL | c.135T>C p.T45= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV100920990; called by muse, varscan2
- ARHGAP9 | c.1110A>G p.S370= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99954864; called by muse, mutect2, varscan2
- ARHGEF26 | c.459C>T p.P153= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs1217381976, COSV100726719; called by muse, mutect2, varscan2
- ARMC5 | c.1011T>C p.P337= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV99192990; called by muse, mutect2, varscan2
- ATP13A3 | c.3369G>A p.L1123= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs376934418; called by muse, mutect2, varscan2
- ATRX | c.4041G>A p.V1347= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV100971687, COSV64879418; called by muse, varscan2
- BAZ1B | c.2697C>T p.R899= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100290250; called by muse, mutect2, varscan2
- C1orf115 | c.390G>A p.P130= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs371210801; called by muse, mutect2, varscan2
- CA12 | c.921A>G p.S307= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV99458946; called by muse, mutect2, varscan2
- CACNA1G | c.1932C>T p.C644= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100662821; called by muse, mutect2, varscan2
- CACNA2D3 | c.1857G>A p.A619= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs745684927, COSV55535817; called by muse, mutect2, varscan2
- CAMTA1 | c.486C>T p.H162= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV100352903; called by muse, mutect2, varscan2
- CATSPER1 | c.1884G>A p.T628= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs370158610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP290 | c.4989A>G p.K1663= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV100470247; called by muse, mutect2, varscan2
- CEP76 | c.1764T>C p.P588= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100043086; called by muse, mutect2, varscan2
- CERS3 | c.1065G>A p.E355= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99433090; called by muse, mutect2, varscan2
- CHD5 | c.4464C>T p.D1488= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs776786583, COSV99315597; called by muse, mutect2, varscan2
- CHD8 | c.4605A>G p.G1535= (on ENST00000646647 / NM_001170629.2; = p.G1256= on NM_020920.4) | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs748561663, COSV100783891; called by muse, mutect2, varscan2
- CIT | c.3258C>T p.R1086= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99951486; called by muse, mutect2, varscan2
- CLCN4 | c.930C>A p.P310= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1421307675, COSV101074137, COSV66465320; called by muse, mutect2, varscan2
- CLDN10 | c.58C>T p.L20= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100176317; called by muse, mutect2, varscan2
- CLOCK | c.60T>C p.S20= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100012097; called by muse, mutect2, varscan2
- CLPTM1 | c.1032G>A p.S344= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs1285222393, COSV100494110; called by muse, mutect2, varscan2
- COIL | c.150C>T p.G50= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99538472; called by muse, mutect2, varscan2
- COL6A2 | c.1263C>T p.G421= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs778836612, COSV100154537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPG2 | c.222G>A p.T74= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs1554460979, COSV58405754; called by muse, mutect2, varscan2
- CPNE5 | c.894C>T p.Y298= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs1048732900, COSV99783454; called by muse, mutect2, varscan2
- CRBN | c.225C>T p.D75= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs577750138, COSV99214323; called by muse, mutect2, varscan2
- CTPS2 | c.1317C>T p.H439= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100827102; called by muse, mutect2, varscan2
- CTSL | c.777T>C p.Y259= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as rs764133097, COSV100446785; called by muse, mutect2, varscan2
- DGCR2 | c.1302G>A p.T434= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs201665590, COSV99594149; called by muse, mutect2, varscan2
- DIRAS2 | c.6T>C p.P2= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV101005932; called by muse, mutect2, varscan2
- DLGAP1 | c.681C>T p.C227= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1044349956, COSV100234878; called by muse, mutect2, varscan2
- DNAH1 | c.11229A>G p.E3743= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV101327431; called by muse, mutect2, varscan2
- DNAH11 | c.894T>C p.P298= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100181524; called by muse, mutect2, varscan2
- DNAH11 | c.11526C>T p.G3842= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100181527; called by muse, mutect2, varscan2
- DNMT3B | c.2505C>T p.S835= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs955772228, COSV99145562; called by muse, mutect2, varscan2
- DOP1A | c.7194G>A p.P2398= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs149361394; called by muse, mutect2, varscan2
- DSG4 | c.2316A>G p.A772= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100356567; called by muse, mutect2, varscan2
- EBF2 | c.822C>T p.I274= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs1313952654, COSV68776712; called by muse, mutect2, varscan2
- ENOX2 | c.891C>T p.N297= (on ENST00000338144 / NM_001382520.1; = p.N268= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1434727160, COSV100584732; called by muse, mutect2, varscan2
- EPB41L1 | c.931C>A p.R311= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV99154952; called by muse, mutect2, varscan2
- EZHIP | c.300C>T p.R100= | Silent (SNP) | VAF 39/64 reads (61%) | catalogued as COSV100539979; called by muse, mutect2, varscan2
- FAAP100 | c.1833C>T p.G611= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs201869841; called by muse, mutect2, varscan2
- FBXO24 | c.1299G>A p.L433= (on ENST00000241071 / NM_033506.3; = p.L471= on NM_012172.5) | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV99575834; called by muse, mutect2, varscan2
- FNDC1 | c.213G>A p.E71= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs1268725213, COSV99797466; called by muse, mutect2, varscan2
- FOXN3 | c.1131C>T p.S377= (on ENST00000261302; = p.S355= on NM_005197.4) | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs750647040, COSV54313370; called by muse, mutect2, varscan2
- FRMD4B | c.2202C>T p.S734= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV101273691; called by muse, mutect2, varscan2
- FSTL4 | c.2520T>C p.G840= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99534164; called by muse, mutect2, varscan2
- FUBP3 | c.372C>A p.P124= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV60517529; called by muse, mutect2, varscan2
- GJA4 | c.493C>T p.L165= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100654793; called by muse, mutect2, varscan2
- GJB5 | c.222G>A p.V74= | Silent (SNP) | VAF 55/104 reads (53%) | catalogued as COSV100258775; called by muse, mutect2, varscan2
- GKAP1 | c.726T>C p.H242= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100897802; called by muse, mutect2, varscan2
- GMDS | c.1008C>T p.C336= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101070658; called by muse, mutect2, varscan2
- GNL2 | c.210A>G p.T70= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100895063; called by muse, mutect2, varscan2
- HCN2 | c.2091C>T p.Y697= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs773062478, COSV52120469; called by muse, mutect2, varscan2
- HELZ2 | c.6675G>T p.S2225= (on ENST00000467148 / NM_001037335.2; = p.S1656= on NM_033405.3) | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1464155019, COSV101427644; called by muse, mutect2
- HEPHL1 | c.2643T>C p.C881= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1328780987, COSV100244642; called by muse, mutect2, varscan2
- HLA-G | c.561G>A p.T187= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100827242; called by muse, mutect2, varscan2
- HOPX | c.39G>A p.Q13= (on ENST00000317745; = p.Q31= on NM_032495.6) | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as rs1397303015, COSV100497117; called by muse, mutect2, varscan2
- HSPG2 | c.6444C>T p.P2148= | Silent (SNP) | VAF 54/103 reads (52%) | catalogued as rs376495654, COSV101021457; called by muse, mutect2, varscan2
- HYOU1 | c.1701C>T p.S567= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs202017398, COSV101345710; called by muse, mutect2
- IFRD1 | c.1227T>C p.A409= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99134519; called by muse, mutect2, varscan2
- IGLV6-57 | c.291C>A p.I97= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101135343; called by muse, mutect2, varscan2
- IGSF3 | c.2022G>A p.L674= (on ENST00000369486 / NM_001007237.3; = p.L694= on NM_001542.4) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100605206; called by muse, mutect2, varscan2
- IGSF5 | c.1092T>C p.P364= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV101012154; called by muse, mutect2, varscan2
- IL4R | c.288G>A p.A96= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99405499; called by muse, mutect2, varscan2
- JUN | c.885G>A p.A295= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV64664934; called by muse, mutect2, varscan2
- KAT6A | c.2058G>T p.L686= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99706123; called by muse, mutect2, varscan2
- KBTBD4 | c.336T>C p.A112= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99772560; called by muse, mutect2, varscan2
- KCNQ4 | c.679C>T p.L227= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100714472; called by muse, mutect2, varscan2
- KIF18B | c.1452C>T p.T484= (on ENST00000593135 / NM_001265577.2; = p.T496= on NM_001264573.2) | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100192740; called by muse, mutect2, varscan2
- KIF23 | c.1233G>A p.V411= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99532850; called by muse, mutect2, varscan2
- KLHL17 | c.1818C>T p.A606= | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as rs1405029500, COSV100647648; called by muse, mutect2, varscan2
- KMT2B | c.6027C>T p.A2009= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs371641922; called by muse, mutect2, varscan2
- LAMA2 | c.1275C>A p.V425= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101370181; called by muse, mutect2, varscan2
- LENG8 | c.612T>C p.Y204= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs769624284, COSV100458259; called by muse, mutect2, varscan2
- LRP1 | c.4456C>T p.L1486= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99677919; called by muse, mutect2, varscan2
- LZTS3 | c.1158G>A p.Q386= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1483379667, COSV100232420; called by muse, mutect2, varscan2
- MAN2A2 | c.1680G>A p.R560= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100848074; called by muse, mutect2, varscan2
- MAOA | c.186C>T p.Y62= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs180855715, COSV100109122; called by muse, mutect2, varscan2
- MAU2 | c.1321C>T p.L441= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs922403534, COSV99449330; called by muse, mutect2, varscan2
- MET | c.3378C>T p.T1126= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs201111132, COSV100577545; ClinVar: likely benign; called by muse, mutect2, varscan2
- MMP16 | c.930C>T p.R310= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs1175569808, COSV99691009; called by muse, mutect2, varscan2
- MNT | c.1485T>C p.P495= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV99438430; called by muse, mutect2, varscan2
- MORC4 | c.408C>A p.A136= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99717797; called by muse, mutect2, varscan2
- MSANTD3 | c.450C>T p.C150= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs755534896, COSV100614960, COSV58490778; called by muse, mutect2, varscan2
- MT1E | c.42G>C p.T14= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as COSV100042408; called by muse, mutect2
- MUC16 | c.11019C>T p.P3673= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV101202327; called by muse, mutect2, varscan2
- MYO10 | c.393G>A p.P131= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs777894398, COSV101549947; called by muse, varscan2
- NBAS | c.6733C>T p.L2245= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99872185; called by muse, mutect2, varscan2
- NECAB1 | c.216T>C p.I72= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1227944528, COSV101341258; called by muse, mutect2, varscan2
- NEO1 | c.1380G>T p.R460= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV99981320, COSV99983019; called by muse, mutect2, varscan2
- NR1D2 | c.462C>T p.N154= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV100437631; called by muse, mutect2, varscan2
- NRG1 | c.384C>T p.T128= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV55178031, COSV99829976; called by muse, mutect2, varscan2
- OR4Q3 | c.771C>T p.S257= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100057564; called by muse, mutect2, varscan2
- OR9G1 | c.441A>G p.S147= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV100380612; called by muse, mutect2, varscan2
- OTX1 | c.303C>T p.S101= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99246481; called by muse, mutect2, varscan2
- PBXIP1 | c.486G>A p.R162= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100870143; called by muse, mutect2, varscan2
- PCDH19 | c.555C>A p.S185= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99721126; called by muse, mutect2, varscan2
- PCDHA7 | c.1170G>A p.T390= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV65346327; called by muse, mutect2, varscan2
- PCDHB2 | c.1924C>T p.L642= | Silent (SNP) | VAF 79/162 reads (49%) | catalogued as COSV99167231; called by muse, varscan2
- PCDHGA8 | c.2190C>T p.G730= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs990026940, COSV99549935; called by muse, mutect2, varscan2
- PDCD6IP | c.2229G>A p.A743= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs779305954, COSV100219260; called by muse, mutect2, varscan2
- PDE10A | c.366T>C p.F122= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs778814596, COSV100606225; called by muse, mutect2, varscan2
- PGBD5 | c.1113C>T p.A371= (on ENST00000525115; = p.A440= on NM_001258311.2) | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs147906823; called by muse, mutect2, varscan2
- PKIG | c.102C>T p.S34= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs780693773, COSV100596119; called by muse, mutect2, varscan2
- PKMYT1 | c.162G>A p.P54= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs374098858; called by muse, mutect2, varscan2
- PMS2 | c.993C>T p.C331= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs186577215, COSV56219848; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- PPID | c.597C>T p.G199= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs775479225, COSV100307037; called by muse, mutect2, varscan2
- PPM1G | c.1071C>T p.G357= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV100085487; called by muse, mutect2, varscan2
- PRRT3 | c.942C>T p.D314= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs370676875; called by muse, mutect2, varscan2
- PSMD14 | c.891C>T p.V297= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV101271577; called by muse, mutect2, varscan2
- RAVER1 | c.1023G>A p.A341= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs756023256, COSV99533229; called by muse, mutect2, varscan2
- RBM33 | c.1989C>T p.T663= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs777514318, COSV100265832; called by muse, mutect2, varscan2
- ROBO3 | c.2007G>A p.A669= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs753075502, COSV101185251; called by muse, mutect2, varscan2
- ROPN1 | c.306T>C p.D102= | Silent (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- RPE65 | c.843C>T p.S281= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV52018924, COSV99254418; called by muse, mutect2, varscan2
- RREB1 | c.1347G>A p.Q449= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV100619991; called by muse, mutect2, varscan2
- RYR3 | c.12528G>A p.A4176= (on ENST00000389232; = p.A4177= on NM_001036.6) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs555347756, COSV101215295; called by muse, mutect2, varscan2
- SAMD9L | c.1518C>T p.S506= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs560813720, COSV59081443; called by muse, mutect2, varscan2
- SEPHS2 | c.27C>A p.A9= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV101529354; called by muse, mutect2
- SERPINB1 | c.858C>T p.S286= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs755709516, COSV66313974; called by muse, mutect2, varscan2
- SESTD1 | c.609G>A p.S203= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs756012108, COSV100091018; called by muse, mutect2, varscan2
- SH2D2A | c.216C>T p.A72= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs754523406, COSV100949221, COSV63885554; called by muse, mutect2, varscan2
- SLC44A1 | c.1338A>G p.G446= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100570762; called by muse, mutect2, varscan2
- SLC45A1 | c.738C>T p.Y246= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs186437701; called by muse, mutect2, varscan2
- SLC6A5 | c.306C>T p.G102= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100117261; called by muse, mutect2, varscan2
- SLC7A4 | c.1464A>G p.S488= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100298983; called by muse, mutect2, varscan2
- SLC8B1 | c.1209A>G p.S403= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1244640022, COSV99176875; called by muse, mutect2, varscan2
- SLC9A3R2 | c.234T>C p.A78= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV101424300; called by muse, mutect2, varscan2
- SOWAHB | c.57C>G p.G19= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100530821; called by muse, mutect2, varscan2
- SPTLC3 | c.1017C>T p.H339= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100983323; called by muse, mutect2, varscan2
- SRPK2 | c.87A>G p.P29= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs561288645, COSV61961245; called by muse, mutect2, varscan2
- SRPK3 | c.856C>T p.L286= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99473514; called by muse, mutect2, varscan2
- STAB1 | c.4956G>C p.R1652= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV100402475; called by muse, mutect2, varscan2
- STK10 | c.858G>A p.A286= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs753285320, COSV99452541; called by muse, mutect2, varscan2
- SUCO | c.2112T>C p.S704= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99744110; called by muse, mutect2, varscan2
- SUN2 | c.1476C>A p.I492= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99325951; called by muse, mutect2, varscan2
50 further variants in this file (0 protein-altering or splice-affecting, 27 silent, 23 other) are not listed here.
